Somatic mutation profile of tumor specimen 0E1UJU from CCDI case PBCWWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1UJU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba14fa56-823b-43cb-9b4c-4d1ff1099f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1UJB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f982c5-ceb4-4368-ad83-3c3a9304a111

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 2, Intron 2, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXorf65 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV99340349; called by muse, varscan2
- GGACT | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1229786070; called by muse, varscan2
- MYO18B | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100122565; called by muse, varscan2
- NRXN1 | c.3651C>A p.F1217L | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs759349308; called by muse, varscan2
- PABPN1L | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 177/412 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs564394520; called by muse, varscan2
- ADGRF2 | c.1054G>T p.E352* (on ENST00000296862 / NM_001368115.2; = p.E284* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 93/352 reads (26%) | called by muse, varscan2
- BBC3 | c.289dup p.H97Pfs*153 (on ENST00000449228 / NM_001127240.3; = p.T63Hfs*166 on NM_014417.5) | Frame Shift Ins (INS) | VAF 49/301 reads (16%) | called by pindel, varscan2
- DGAT2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, varscan2
- HOXD11 | c.421T>G p.F141V | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.437); called by muse, varscan2
- KCNQ2 | c.1987G>A p.E663K (on ENST00000359125 / NM_172107.4; = p.E635K on NM_004518.6) | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, varscan2
- LILRB3 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 97/390 reads (25%) | called by muse, varscan2
- PMEL | c.1900A>G p.S634G | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, varscan2
- PMEL | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- TBC1D12 | c.1413_1415del p.X471_splice | Splice Site (DEL) | VAF 34/134 reads (25%) | called by pindel, varscan2
- AK9 | c.5100C>G p.L1700= | Silent (SNP) | VAF 99/378 reads (26%) | called by muse, varscan2
- CEACAM19 | c.507C>T p.A169= | Silent (SNP) | VAF 70/238 reads (29%) | catalogued as rs1390372768; called by muse, varscan2
- FYCO1 | c.3390C>T p.L1130= | Silent (SNP) | VAF 126/287 reads (44%) | called by muse, varscan2
- SHANK2 | c.3321G>T p.L1107= | Silent (SNP) | VAF 56/200 reads (28%) | called by muse, varscan2
- DENND1C | c.1584-62G>T | Intron (SNP) | VAF 65/187 reads (35%) | called by muse, varscan2
- PKD1L2 | n.2887C>T | RNA (SNP) | VAF 66/384 reads (17%) | catalogued as rs374473438; called by muse, varscan2
- R3HDM4 | c.226+60T>C | Intron (SNP) | VAF 54/144 reads (38%) | called by muse, varscan2
